CCDI case PBCLHA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/c21b98d2-0559-4e4d-9ae9-2a1b6e6e010d

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.8 years (1,019 days).

Biospecimens (3 samples)
- Sample 0DUFDF: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DUFE4: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DUFED: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
